Surgical pathology report (de-identified scan), TCGA case TCGA-44-6144, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-6144-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

SPECIMEN

- A. Right upper lobe
- B. R4
- C. Level 7

CLINICAL NOTES

PRE-OP DIAGNOSIS: Lung cancer

GROSS DESCRIPTION

A. Received fresh for tissue procurement labeled "right upper lobe" is a 285 gm, 19 x 12.8 x 3.8 cm lobectomy specimen with attached 1 cm in length, 1.7 x 0.8 cm in diameter bronchial stump. The pleura is focally hemorrhagic, tan-pink-gray. On sectioning, there is a stellate, 2 x 1.8 x 1.8 cm rubbery pale tan lesion within the inferior portion of the specimen. The lesion extends to within 2.4 cm of the pleural surface (inked blue). A portion of tumor and a portion of normal parenchyma are submitted for tissue procurement as requested. The parenchyma throughout the remainder of the specimen is spongiform, tan-pink to red-purple without additional mass lesion or abnormality. Two slightly rubbery gray-black tissues in keeping with lymph nodes measuring up to 1.3 cm in greatest dimension are recovered from the hilar region of the specimen. e tentative sections are submitted in ten blocks as labeled. [REDACTED]

BLOCK SUMMARY: 1 - Bronchial stump margin; 2 - vascular margin; 3 - tumor to inked pleural surface; 4-6 - tumor to adjacent parenchyma; 7&8 - random including subpleural hem [REDACTED]; 9 - one whole lymph node; 10 - one bisected lymph node. [REDACTED]

B. Received fresh, subsequently fixed in formalin, labeled "B. R4" multiple black pink irregular soft tissue fragments which have an aggregate measurement of 0.8 x [REDACTED] 0.3 cm. The specimens are entirely submitted in one cassette. [REDACTED]

C. Received fresh, subsequently fixed in formalin labeled "level 7" are multiple black pink red irregular soft tissue fragments which have an aggregate measurement of 1.5 x [REDACTED] x 0.7 cm. [REDACTED] specimens are entirely submitted in one cassette. [REDACTED].

[REDACTED]

[REDACTED]

MICROSCOPIC DESCRIPTION

A, B and C. Microscopic examination performed and summarized below:

Histologic type: Adenocarcinoma.
Histologic grade: Moderately differentiated.
Primary tumor (pT): Is 2 cm. in greatest dimension with no extension to the pleura and no involvement of the large bronchi (pT1a).
Margins of resection: Negative for tumor.

[page 2 of 2]
Direct extension of tumor: Tumor invades pulmonary parenchyma with no extension to pleura and no extension to main stem bronchi.
Venous (large vessel) invasion: Present (best seen in slide A5).
Arterial (large vessel) invasion: Absent.
Lymphatic (small vessel) invasion: Present, best seen in slide A6.
Regional lymph nodes (pN): Two lymph nodes are dissected from specimen A. They are both negative for metastatic tumor. One lymph node is dissected from specimen B and 4 lymph nodes from specimen C (pN0).
Distant metastasis (pM): Cannot evaluate pMx.
Other findings: There is an area of intraparenchymal pulmonary hemorrhage with dropout of pulmonary parenchyma. This is somewhat non-specific but is associated with some hemosiderin and thus does not appear procedural to this surgery. It could be secondary to a pulmonary embolus, but no organized thromboembolus is identified adjacent to the hemorrhage. No intraparenchymal metastasis is identified.

5x1, 3x2

DIAGNOSIS

- A. Lung, right upper lobe, lobectomy:
- Adenocarcinoma 2 cm. in greatest dimension, pleura and main stem bronchus negative for tumor (pT1a).
- Venous space invasion and lymphatic space invasion present.
- Resection margins are negative for tumor.
- Separate parenchymal hematoma.
- Two lymph nodes negative for metastatic tumor (0/2).
- B. Lymph node, R4, biopsy:
- Single lymph node negative for metastatic tumor (0/1).
- C. Lymph nodes, level 7, biopsy:
- Four lymph nodes negative for metastatic tumor (0/4).
-

--- End Of Report ---

Source: NCI Genomic Data Commons file 7f1465d6-22a8-4886-8dff-d7d00c74d692 (TCGA-44-6144.1DFAF7F2-8902-403C-B903-DC59C8156D17.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).